Gene-level copy-number profile of tumor specimen TCGA-IG-A51D-01A from TCGA case TCGA-IG-A51D, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.7 years (23,259 days).
Specimen TCGA-IG-A51D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b8d454bf-7047-4a53-b051-91d092e0c614.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A51D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7da6fb40-4368-4cbb-829d-9bb73eb2bc3b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 867; copy number 2: 9,380; copy number 3: 30,704; copy number 4: 14,706; copy number 5: 684; copy number 6: 898; copy number 7: 2,302; copy number 8: 99; copy number 11: 79; copy number 12: 39; copy number 15: 21; copy number 18: 2; copy number 23: 24; copy number 27: 11; copy number 43: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A51D-01A-11D-A25X-01): tumor purity 0.38, ploidy 3.31, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,581 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 7–8 (broad region; genes not listed).
- chr7:70,972–10,779,944, 220 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:84,847,877–88,756,725, 45 genes, copy number 12–27: AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1.
- chr7:88,794,106–88,795,737, 1 gene, copy number 18: TEX47.
- chr7:91,264,433–105,115,019, 364 genes, copy number 7–11 (broad region; genes not listed).
- chr7:105,439,661–105,600,875, 6 genes, copy number 12 (within-gene range 2–12): PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2.
- chr8:36,764,445–40,520,158, 94 genes, copy number 8 (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 43 (within-gene range 4–43): AP003071.5.
- chr11:69,147,228–71,252,577, 48 genes, copy number 15–43 (within-gene range 2–43): AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr20:11,234,170–11,345,855, 2 genes, copy number 7: AL049649.1, RPS11P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
